Somatic mutation profile of tumor specimen 0DIFIX from CCDI case PBBVLZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.7 years (3,169 days).
Specimen 0DIFIX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67f1d749-4ebf-42ab-af77-ee3accf403cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIFII (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/229b9b66-b5a1-4d3e-a1a2-e068f1357a40

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Intron 2, Splice Site 2, Nonsense Mutation 2, 5'UTR 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACIN1 | c.3553C>T p.R1185C | Missense Mutation (SNP) | VAF 218/846 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs200247829; called by muse, mutect2, varscan2
- AHNAK | c.11765A>G p.D3922G | Missense Mutation (SNP) | VAF 263/604 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs1399560728; called by muse, mutect2, varscan2
- ARHGAP6 | c.2297C>T p.A766V (on ENST00000337414 / NM_013427.3; = p.A563V on NM_013423.3) | Missense Mutation (SNP) | VAF 60/586 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs777020088; called by mutect2, varscan2
- ARHGEF28 | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 368/1120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373108367, COSV104383098; called by muse, mutect2
- CFAP53 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 104/1008 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs780604229; called by muse, mutect2
- COL11A2 | c.4288G>T p.D1430Y (on ENST00000341947 / NM_080680.3; = p.D1323Y on NM_080679.2) | Missense Mutation (SNP) | VAF 154/1012 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs985479138; called by muse, mutect2, varscan2
- DDX21 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 338/909 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs926485610; called by muse, varscan2
- EDARADD | c.622C>T p.R208C (on ENST00000334232 / NM_145861.4; = p.R198C on NM_080738.4) | Missense Mutation (SNP) | VAF 115/561 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs750157040, COSV62063344; called by muse, mutect2, varscan2
- EMILIN2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 75/912 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772348013, COSV54420928; called by muse, mutect2
- EVPL | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 139/666 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs750569215; called by muse, mutect2, varscan2
- HLA-DQA2 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 114/1163 reads (10%) | catalogued as COSV100890820; called by muse, mutect2
- MAGEB10 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 149/696 reads (21%) | catalogued as COSV100775207; called by muse, mutect2, varscan2
- OR4A15 | c.357T>A p.D119E | Missense Mutation (SNP) | VAF 40/817 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs1286763221; called by muse, mutect2
- OR7D4 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV58071313; called by muse, mutect2, varscan2
- PHF24 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 146/2003 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs945096374; called by muse, mutect2
- PTPRH | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 92/737 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs149834920; called by muse, mutect2, varscan2
- TENM4 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 173/383 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1410637100; called by muse, mutect2, varscan2
- TSSK1B | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 141/1061 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs762478599, COSV66814892; called by muse, mutect2, varscan2
- ZNF462 | c.6799C>T p.R2267C | Missense Mutation (SNP) | VAF 117/489 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as rs148065903; called by muse, mutect2, varscan2
- AIFM3 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 78/574 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AKT2 | c.442-1G>A p.X148_splice | Splice Site (SNP) | VAF 263/772 reads (34%) | called by muse, mutect2, varscan2
- BRCC3 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 112/1242 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.127); called by muse, mutect2
- CACNA2D2 | c.3449T>C p.L1150P (on ENST00000479441 / NM_001174051.3; = p.L1143P on NM_006030.4) | Missense Mutation (SNP) | VAF 38/978 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- CALR3 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 161/1376 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- COL7A1 | c.4636-2A>G p.X1546_splice | Splice Site (SNP) | VAF 68/652 reads (10%) | called by muse, mutect2, varscan2
- DDX58 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 238/1072 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FAM184A | c.1111C>A p.R371S | Missense Mutation (SNP) | VAF 172/1436 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- PTCH1 | c.283C>A p.Q95K | Missense Mutation (SNP) | VAF 146/164 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, varscan2
- PTGFR | c.500C>G p.A167G | Missense Mutation (SNP) | VAF 168/1312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTTN | c.6006T>G p.H2002Q | Missense Mutation (SNP) | VAF 108/1064 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- SRGAP1 | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 277/861 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- AURKC | c.844C>T p.L282= (on ENST00000302804 / NM_001015878.2; = p.L248= on NM_003160.3) | Silent (SNP) | VAF 73/615 reads (12%) | called by muse, mutect2, varscan2
- COL4A2 | c.4347C>T p.P1449= | Silent (SNP) | VAF 191/653 reads (29%) | catalogued as rs375772742; ClinVar: likely benign; called by muse, mutect2, varscan2
- JOSD1 | c.246C>T p.Y82= | Silent (SNP) | VAF 163/1279 reads (13%) | catalogued as rs1486222771, COSV53266303; called by muse, mutect2, varscan2
- MTRNR2L5 | c.54A>G p.L18= | Silent (SNP) | VAF 78/924 reads (8%) | called by muse, mutect2
- PSG7 | c.570T>C p.T190= | Silent (SNP) | VAF 81/237 reads (34%) | catalogued as rs1182765729; called by muse, mutect2, varscan2
- RNF227 | c.459G>T p.R153= | Silent (SNP) | VAF 76/434 reads (18%) | called by muse, mutect2, varscan2
- SALL3 | c.1611G>A p.A537= | Silent (SNP) | VAF 237/407 reads (58%) | catalogued as rs1018660920, COSV101609897, COSV73305820; called by muse, mutect2, varscan2
- SESN3 | c.489A>G p.A163= | Silent (SNP) | VAF 199/708 reads (28%) | called by muse, mutect2, varscan2
- SORCS2 | c.1263C>T p.G421= | Silent (SNP) | VAF 82/515 reads (16%) | catalogued as rs747441895, COSV61165619; called by muse, mutect2, varscan2
- TGM4 | c.909G>A p.T303= | Silent (SNP) | VAF 88/770 reads (11%) | catalogued as COSV56092960; called by mutect2, varscan2
- ARHGAP4 | c.682-301G>A | Intron (SNP) | VAF 233/567 reads (41%) | catalogued as rs1348086519, COSV63133283; called by muse, varscan2
- ITGA7 | c.*30G>T | 3'UTR (SNP) | VAF 55/330 reads (17%) | called by muse, mutect2, varscan2
- MSTO1 | c.561-18del | Intron (DEL) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- NCF4 | c.*9T>C | 3'UTR (SNP) | VAF 343/758 reads (45%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 16/143 reads (11%) | called by muse, varscan2
- TOMM34 | c.-64A>G | 5'UTR (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
